CCDI case PBCIED — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/3084d0ec-0b33-4601-92e6-5c475d020c7f

Demographics
Sex at birth: male.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.1 years (3,694 days).

Biospecimens (3 samples)
- Sample 0DSI7I: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSI89: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSI8H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
